Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A4IJ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A4IJ-01A (Primary Tumor).

Gross Description: In bladder, there are an invasive tumor, ill - margins with 2x2x1.5cm in size, soft and pink-gray surface.

Microscopic Description: Tumor cells are prominent hyperplastic for arranging to form papillary or groups or trabeculae. Tumor invades in muscle. Tumor cells have quite scant and eosinophilic or clear cytoplasm. Nuclei are enlarged and variability in shape and size, irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are present. Tumor invades in muscle. Stroma is hemorrhage and invasion of lymphocytes.

Diagnosis Details: Infiltrating urothelial papillary carcinoma, High-grade

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 2 x 2 x 1.5 cm

Tumor features: None specified

Histologic type: Papillary transitional cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Muscularis propria

Lymph nodes: Not specified

Lymphatic invasion: Present

Venous invasion: Present

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0 -3
carcinoma, papillary transitional cell
8130/3
Site: bladder, nos C67.9
JW
10/2/12

HIP Discrepancy		X
Primary Malignancy History		X
Duration, Previous Primary Noted		X
Reviewed:	KMI	9/25/12

Source: NCI Genomic Data Commons file 4be01f3f-7051-4545-b64d-e5331bc7dec9 (TCGA-E7-A4IJ.E926015A-3299-4F9B-AA80-3D46F3CF96C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).